MMRF case MMRF_1112 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/74f00e60-0c8e-4d4d-b7d1-1cedcf836391

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.5 years (21,725 days); ISS stage: II; Days to last known disease status: 1,809 days (5.0 years); Days to last follow up: 1,809 days (5.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 346 days; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 489 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 489 days (1.3 years); Days to treatment end: 685 days (1.9 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,316 days (3.6 years); Days to treatment end: 1,358 days (3.7 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,316 days (3.6 years); Days to treatment end: 1,379 days (3.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,385 days (3.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Beta 2 Microglobulin 2.74 µg/mL; Lactate Dehydrogenase 1.27 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 10.9 g/dL; Glucose 5.94 mmol/L.
- Day 90 (ECOG 3): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Beta 2 Microglobulin 1.96 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 5.94 mmol/L.
- Day 190 (ECOG 0): M Protein 0.1 g/dL; Beta 2 Microglobulin 1.21 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 13.1 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 7.37 mmol/L.
- Day 274 (ECOG 1): M Protein 0.2 g/dL; Hemoglobin 8.93 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.33 mmol/L.
- Day 449 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Beta 2 Microglobulin 1.91 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 534: M Protein 0.2 g/dL; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 615 (ECOG 1): Beta 2 Microglobulin 1.73 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.35 mmol/L.
- Day 722 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.83 mg/dL; Immunoglobulin G 12.3 g/L; Beta 2 Microglobulin 1.83 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.07 mmol/L.
- Day 806 (ECOG 0): M Protein 0 g/dL; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.77 mmol/L.
- Day 909 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.81 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 986 (ECOG 1): Hemoglobin 8.56 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.28 mmol/L.
- Day 1,093 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 2.92 g/L; Immunoglobulin M 0.98 g/L; Beta 2 Microglobulin 2.33 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L.
- Day 1,186 (ECOG 1): Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 6.05 mmol/L.
- Day 1,260 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Beta 2 Microglobulin 2.08 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.94 mmol/L.
- Day 1,358 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Beta 2 Microglobulin 3.49 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 10.9 g/dL; Glucose 5.12 mmol/L.
- Day 1,542 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 7.59 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 7.7 mmol/L.
- Day 1,626 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.32 g/L; Immunoglobulin A 5.76 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.11 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 1,709: Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 5.72 mmol/L.
- Day 1,809: Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 2.88 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.

Other clinical attributes
- Day 1: Weight: 57 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1112_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,186 days (3.2 years).
- Sample MMRF_1112_3_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1,186 days (3.2 years).
